Surgical pathology report (de-identified scan), TCGA case TCGA-EY-A4KR, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of North Carolina, specimen TCGA-EY-A4KR-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Lymph nodes, right pelvic, lymphadenectomy

- Metastatic high grade serous adenocarcinoma in three of three lymph nodes (3/3)
- Largest focus measures 2 cm

B: Uterus, cervix, and bilateral fallopian tubes and ovaries, hysterectomy and bilateral salpingo-oophorectomy:

Location of tumor: Endometrium

Histologic type: Serous adenocarcinoma

Histologic grade (FIGO): High grade

Extent of invasion:

- Through myometrium and into, but not through, serosa
- Lower uterine segment, cervix, and adnexa
- Lymph nodes

Myometrial invasion: outer half

Depth: 2.89 cm Wall thickness: 2.9 cm Percent: >99% (slide B10)

Serosal involvement: Tumor invades into, but not through, the serosa

Lower uterine segment involvement: Present

Cervical involvement: Present; endocervical glands and stroma

Adnexal involvement (see below): Present

Other sites: Not applicable

Cervical margin and distance: Negative, 0.6 cm

Lymphovascular space invasion: Present

Regional lymph nodes (see other specimens):

Total number involved: 8

Total number examined: 8

ICD-0-3

adenocarcinoma, serous, NOS 8441/3

Site: endometrium C54.1

hw
10/2/12

[page 2 of 5]
Other pathologic findings: Multiple leiomyomas, up to 7.5 cm in greatest dimension

AJCC Pathologic Stage: pT3a pN1
FIGO (classification) Stage grouping: IIIC1

These stages are based on information available at the time of this report, and are subject to change pending additional information and clinical review.

Ovaries, right and left, bilateral oophorectomy

- Extensive lymphovascular space invasion bilaterally with few foci of parenchymal invasion in one ovary, measuring up to 0.2 cm (see comment)
- No ovarian surface involvement
- Epithelial inclusion cysts
- Physiologic changes

Fallopian tube, right, salpingectomy:

- High grade serous adenocarcinoma involving tubal wall and fimbria with obliteration of lumen

Fallopian tube, left, salpingectomy:

- High grade serous adenocarcinoma involving tubal wall and fimbria with obliteration of lumen

C: Lymph nodes, left obturator, lymphadenectomy

- Metastatic high grade serous adenocarcinoma in three of four lymph nodes (4/4)
- Largest focus measures 1.5 cm

D: Lymph nodes, left pelvic, lymphadenectomy

- Metastatic high grade serous adenocarcinoma in one of one lymph node (1/1)
- Largest focus measures 1.9 cm

Comment:

The bulk of the serous adenocarcinoma is present in the uterus and the pattern of involvement is most consistent with a uterine primary with metastases to bilateral adnexae and lymph nodes.

Both ovaries show lymphovascular space invasion by serous adenocarcinoma. One section from each ovary was submitted initially, and then the remainder of each ovary was submitted at my request. When the ovaries were removed from formalin, we found that they had not been designated "right" and "left" after the initial sections were taken. Therefore, I cannot

[page 3 of 5]
determine which ovary shows parenchymal involvement.

Intraoperative Consult Diagnosis:

An intraoperative consultation was requested by Dr. in

FSA1: Right pelvic, biopsy
- Serous carcinoma

Drs.

Frozen Section Pathologist:

Clinical History:

-year-old female with a history of high grade serous carcinoma of the endometrium.

Gross Description:

Specimen A is labeled "right pelvic" and is received fresh for frozen section and placed in formalin. The specimen consists of two lymph node candidates; 3.5 cm and 0.9 cm. Representative section of largest lymph node plus entire smaller lymph node is frozen as FSA1. The remaining lymph node and tissue are submitted as per block summary.

Block Summary:

FSA1 - Frozen section remnant

A1-A3 - One lymph node (frozen section remnant), bisected

A4-A5 - One lymph node, bisected,

Specimen B is labeled "uterus, cervix, tubes and ovaries".

Adnexa: Present, attached

Weight: 768 grams

Shape: Distorted by multiple subserosal myomatous nodules

Dimensions:

height: 13.0 cm

anterior to posterior width: 11.0 cm

breadth at fundus: 12.0 cm

Serosa: There is a 9.0 x 6.5 cm area of serosal adhesion at the fundus. The remaining serosa is gray, smooth, and glistening.

Cervix: 3.2 cm in diameter.

ectocervix: Tan, smooth, glistening.

endocervix: The endocervical lining is diffusely covered by

[page 4 of 5]
white firm nodules.

length of endocervical canal: 4.1 cm

Endomyometrium:

length of endometrial cavity: 6.4 cm

width of endometrial cavity at fundus: 6.0 cm

tumor findings:

dimensions: 9.4 x 6.4 x 2.5 cm (protruding into the endometrial cavity)

appearance: Tan, friable with focally firm areas

location and extent: The mass involves the entire endometrial cavity and lower uterine segment and extends into the endocervical canal.

myometrial invasion: Outer one-half

thickness of myometrial wall at deepest gross invasion: The mass grossly extends 2.6 cm into a 2.8 cm thick myometrium.

other findings or comments: There are multiple white, whorled circumscribed myomatous nodules, one of which is entirely calcified. The myomatous nodules range in size from 0.9 cm to 7.5 cm in greatest dimension.

Adnexa:

Right ovary:

dimensions: 2.5 x 2.0 x 1.1 cm

external surface: Grossly unremarkable

cut surface: Grossly unremarkable

Right fallopian tube:

dimensions: 5.5 cm x 0.6 cm

other findings: The distal fallopian tube transitions into a 5.0 x 2.2 x 2.0 cm cyst containing clear fluid. Also noted are focal white, dense areas within the tube. Fimbriae is absent.

Left ovary:

dimensions: 2.8 x 1.5 x 1.1 cm

external surface: Unremarkable

cut surface: Grossly unremarkable

Left fallopian tube:

dimensions: 6.0 cm long x 0.6 cm in diameter with a 4.2 x 2.5 x 2.5 cm clear fluid filled simple cyst at the distal end.

other findings: Sectioning reveals white, gritty fallopian tube wall. No fimbriae present.

Lymph nodes:

Other comments: None

Digital photograph taken: No

Tissue submitted for special investigations: Yes

[page 5 of 5]
Block Summary:

- B1 - Anterior cervix
- B2 - Anterior lower uterine segment
- B3 - Posterior cervix
- B4 - Posterior lower uterine segment
- B5-B6 - Anterior corpus, bisected
- B7 - Anterior corpus, bisected
- B8 - Anterior myometrium with myomatous nodule
- B9 - Posterior corpus, bisected
- B10 - Posterior corpus, bisected
- B11 - Posterior corpus, bisected
- B12 - Right ovary
- B13 - Right fallopian tube
- B14 - Left ovary
- B15 - Left fallopian tube
- B16-B23 - Remainder of ovary (not specified)
- B24-B31 - Other ovary, submitted entirely

Specimen C labeled "left obturator" and is received in formalin and consists of a 5.0 x 2.2 x 1.9 cm fragment of fibroadipose tissue containing 4 lymph node candidates ranging from 1.2 cm to 3.7 cm in greatest dimension. The largest lymph node has white, gritty, nodular cut surface. The lymph nodes are submitted per block summary:

Block Summary:

- C1 - One lymph node, bisected
- C2-C3 - One lymph node, bisected
- C4-C5 - One lymph node bisected
- C6 - One representative section from largest lymph node

Specimen D is labeled "left pelvic" and is received in formalin and consists of a 2.0 x 1.2 x 1.0 cm lymph node with white, gritty cut surface. Representative section is submitted in block D1.

HPA Discrepancy		

10/1/12

Source: NCI Genomic Data Commons file 5fdb6623-139b-4e5a-b745-44f66ac7f802 (TCGA-EY-A4KR.D8669681-B1D2-4D39-B7BB-5207F901A937.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).